Somatic mutation profile of cancer-model specimen HCM-CSHL-0056-C18-85B (3D Organoid; aliquot HCM-CSHL-0056-C18-85B-01D-A78J-36), derived from the primary tumor of HCMI case HCM-CSHL-0056-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.1 years (27,431 days).
Specimen HCM-CSHL-0056-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a231261-025d-4a8d-b086-31798075f331.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0056-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0056-C18-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd8d5df7-d822-4c6b-b323-5e3d6cb2eede

The open-access MAF lists 193 somatic variants for this specimen: 125 protein-altering or splice-affecting, 45 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 45, Nonsense Mutation 9, Intron 9, RNA 4, Frame Shift Del 3, 3'Flank 3, 5'Flank 3, In Frame Del 2, Splice Region 2, 3'UTR 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 128/308 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 208/425 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 267/581 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 172/408 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5069G>A p.R1690Q | Missense Mutation (SNP) | VAF 126/310 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368756746; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4757C>A p.P1586H | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1467578874; called by muse, mutect2, varscan2
- ANKRD6 | c.1736C>T p.S579L (on ENST00000339746 / NM_001242809.2; = p.S574L on NM_014942.4) | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs750495083; called by muse, mutect2, varscan2
- APC | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 87/174 reads (50%) | catalogued as CM930020, COSV57326188; called by muse, mutect2, varscan2
- APC | c.4230C>A p.C1410* | Nonsense Mutation (SNP) | VAF 99/191 reads (52%) | catalogued as COSV57322030; called by muse, mutect2, varscan2
- ASMTL | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs759594201; called by muse, mutect2, varscan2
- BRD2 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262681711; called by muse, mutect2
- CADPS | c.3385C>T p.R1129* | Nonsense Mutation (SNP) | VAF 90/209 reads (43%) | catalogued as rs748581222, COSV51867184, COSV51891180; called by muse, mutect2, varscan2
- CCDC62 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs755321849; called by muse, mutect2, varscan2
- CDC42BPB | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 135/339 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs749711259, COSV63475201; called by muse, mutect2, varscan2
- CFP | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs1356549018; called by muse, mutect2, varscan2
- CHRNB4 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 150/288 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs368785360; called by muse, mutect2, varscan2
- COL15A1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs145278600, COSV100898092; called by muse, mutect2, varscan2
- COL9A1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1302609073, COSV57892528; called by mutect2, varscan2
- CPAMD8 | c.1990G>A p.A664T (on ENST00000651564; = p.A617T on NM_015692.5) | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs568970755, COSV52236816; called by muse, mutect2, varscan2
- CSMD3 | c.7681C>T p.R2561W (on ENST00000297405 / NM_001363185.1; = p.R2457W on NM_052900.3) | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs756318986, COSV52243175; called by muse, mutect2, varscan2
- DYNC1H1 | c.7502C>T p.S2501F | Missense Mutation (SNP) | VAF 18/634 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV64138883; called by muse, mutect2
- ELAPOR2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs374577797; called by muse, mutect2, varscan2
- ESS2 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs766241326; called by muse, mutect2
- FAM47A | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as rs1304387328, COSV60498436, COSV60500315; called by muse, mutect2, varscan2
- GABRB2 | c.1191G>A p.T397= | Splice Region (SNP) | VAF 60/142 reads (42%) | catalogued as rs373911261; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GAL3ST3 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750515200, COSV61749073; called by muse, mutect2, varscan2
- GRM6 | c.1268G>T p.C423F | Missense Mutation (SNP) | VAF 201/438 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1217441736; called by muse, mutect2, varscan2
- HMCN1 | c.15545G>A p.R5182Q | Missense Mutation (SNP) | VAF 253/552 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs148826584; called by muse, mutect2, varscan2
- IGHE | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 160/314 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs375858136; called by muse, mutect2, varscan2
- ITPR3 | c.2166C>G p.D722E | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.684); catalogued as rs754514992; called by muse, mutect2
- ITPRID1 | c.2122G>T p.V708L | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV60069988; called by muse, mutect2, varscan2
- JAKMIP1 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 142/321 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs781019554, COSV68955286; called by muse, mutect2, varscan2
- KLHL23 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752643631; called by muse, mutect2, varscan2
- KRT27 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 142/290 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs775693252; called by muse, mutect2, varscan2
- LRP2 | c.13650G>T p.K4550N | Missense Mutation (SNP) | VAF 141/314 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1160377420; called by muse, mutect2, varscan2
- LRP2 | c.8623C>T p.R2875C | Missense Mutation (SNP) | VAF 169/361 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1308246487, COSV55547020, COSV55551317; called by muse, mutect2, varscan2
- LRRTM4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 143/315 reads (45%) | catalogued as COSV69138907; called by muse, mutect2, varscan2
- MAP3K19 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV59638072; called by muse, mutect2, varscan2
- MARK4 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs1039550856, COSV53464813; called by muse, mutect2, varscan2
- MLLT6 | c.990_992del p.S338del | In Frame Del (DEL) | VAF 62/170 reads (36%) | catalogued as rs749105834; called by pindel, varscan2
- MPPED1 | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 163/370 reads (44%) | catalogued as rs780341898, COSV100501203; called by muse, mutect2, varscan2
- NEFL | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 240/494 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99648224; called by muse, mutect2, varscan2
- NLGN4X | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 356/358 reads (99%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as rs373602022, COSV52014407; called by muse, mutect2, varscan2
- NLRP12 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 30/557 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs760185291, COSV60747502; called by muse, mutect2
- OCM | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs376247775, COSV54194874; called by muse, mutect2, varscan2
- OR2T33 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 287/845 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as rs777287203, COSV100531481, COSV58816166; called by muse, varscan2
- PARP8 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55855228; called by muse, mutect2, varscan2
- PCDHB2 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 297/641 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV50571098; called by muse, mutect2, varscan2
- PDGFRA | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 219/467 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1060501520, COSV57265097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLG | c.1591G>A p.G531S | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs796052904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIL2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as rs376001677; called by muse, mutect2, varscan2
- PRSS53 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 121/255 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs200170110; called by muse, mutect2, varscan2
- PTPRM | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs773443231; called by muse, mutect2, varscan2
- PTPRZ1 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV66445947; called by muse, mutect2
- RRBP1 | c.3511C>T p.R1171W (on ENST00000377813 / NM_001365613.2; = p.R738W on NM_004587.3) | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1374708828, COSV55698663; called by muse, mutect2, varscan2
- SLC10A1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 166/358 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200362742; called by muse, mutect2, varscan2
- SLC29A4 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs557809993; called by muse, mutect2, varscan2
- SLC2A14 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 103/210 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV61588507; called by muse, mutect2, varscan2
- SPTA1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 219/435 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370498187; called by muse, mutect2, varscan2
- TACSTD2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV64666921; called by muse, mutect2
- TAS2R19 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as rs373198792; called by muse, mutect2, varscan2
- TEX13C | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 249/309 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1423216462; called by muse, varscan2
- TFCP2L1 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs775890940; called by muse, mutect2, varscan2
- TOGARAM2 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs746261840; called by muse, mutect2, varscan2
- TTC30B | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 140/270 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1262312485; called by muse, mutect2, varscan2
- UNC13D | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 183/433 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs150442758, COSV52888047; called by muse, mutect2, varscan2
- USP45 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139278154; called by muse, mutect2, varscan2
- ZNF778 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 157/313 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs573000338, COSV60600736; called by muse, mutect2, varscan2
- ABI1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ACVR2A | c.1251_1253del p.E418del | In Frame Del (DEL) | VAF 28/110 reads (25%) | called by pindel, varscan2
- ACVR2A | c.1432_1435del p.R478Lfs*7 | Frame Shift Del (DEL) | VAF 117/179 reads (65%) | called by mutect2, pindel, varscan2
- ADCYAP1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AGBL1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ANKRD9 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 116/217 reads (53%) | called by muse, mutect2, varscan2
- ARID5B | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARPC5L | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 205/446 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ASB3 | c.381del p.L128* | Frame Shift Del (DEL) | VAF 47/137 reads (34%) | called by mutect2, pindel, varscan2
- BTN3A1 | c.1513C>G p.P505A | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- C11orf96 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 70/181 reads (39%) | called by muse, mutect2
- CCDC7 | c.258A>C p.K86N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); called by muse, varscan2
- COBL | c.3093_3097dup p.S1033Tfs*34 | Frame Shift Ins (INS) | VAF 32/76 reads (42%) | called by pindel, varscan2
- CTRC | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.155); called by muse, mutect2
- DCLRE1B | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ELP2 | c.761G>T p.R254I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ERBIN | c.1206+1G>A p.X402_splice | Splice Site (SNP) | VAF 68/127 reads (54%) | called by muse, mutect2, varscan2
- FAM184B | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FEM1C | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FGFRL1 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 238/452 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FZD10 | c.1609C>A p.R537S | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- GRIK2 | c.2426G>T p.S809I | Missense Mutation (SNP) | VAF 26/453 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- HBM | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 98/230 reads (43%) | called by muse, mutect2, varscan2
- HDAC1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSD17B3 | c.294G>T p.R98S | Missense Mutation (SNP) | VAF 133/325 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IKZF1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPR2 | c.3381G>C p.E1127D | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNB2 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 125/240 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF2A | c.1316T>C p.F439S | Missense Mutation (SNP) | VAF 110/216 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K9 | c.2374A>G p.K792E (on ENST00000554752 / NM_001284230.1; = p.K806E on NM_033141.4) | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2
- MARCHF6 | c.408G>T p.T136= | Splice Region (SNP) | VAF 82/262 reads (31%) | called by muse, mutect2, varscan2
- MSC | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.115); called by muse, mutect2
- NEB | c.11914C>G p.L3972V | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NEK5 | c.2088G>T p.K696N | Missense Mutation (SNP) | VAF 135/302 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NPTX1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 176/568 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- NPY1R | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 121/294 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NR5A1 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARG | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 116/772 reads (15%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCK1 | c.1826A>C p.E609A | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, varscan2
- PHOX2B | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.27); called by muse, mutect2
- PI15 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2
- PLCH1 | c.1834del p.A612Pfs*34 (on ENST00000340059 / NM_001130960.2; = p.A624Pfs*34 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 80/194 reads (41%) | called by mutect2, pindel, varscan2
- PSAT1 | c.1094T>A p.L365* (on ENST00000376588 / NM_058179.4; = p.L319* on NM_021154.5) | Nonsense Mutation (SNP) | VAF 202/426 reads (47%) | called by muse, mutect2, varscan2
- PTX3 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 135/252 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SHOX2 | c.368G>A p.R123H (on ENST00000441443 / NM_006884.3; = p.R147H on NM_003030.4) | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2
- SNRNP200 | c.6038G>A p.R2013H | Missense Mutation (SNP) | VAF 106/269 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, varscan2
- SPATA31A6 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.237); called by muse, mutect2
- STEAP2 | c.1079A>C p.Y360S | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- TBXA2R | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 63/461 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- THOC1 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TNS2 | c.2306C>T p.S769F (on ENST00000314250 / NM_170754.4; = p.S779F on NM_015319.2) | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- TSPYL5 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- TTN | c.25434G>T p.Q8478H (on ENST00000591111; = p.Q7551H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/146 reads (45%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS18 | c.1970G>A p.G657E | Missense Mutation (SNP) | VAF 212/459 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- VSTM2A | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 208/423 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- WDR36 | c.1508C>T p.T503I | Missense Mutation (SNP) | VAF 132/452 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZNF93 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 171/412 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.499); called by muse, varscan2
- AC100868.1 | c.1026C>T p.V342= | Silent (SNP) | VAF 91/198 reads (46%) | catalogued as rs368039478; called by muse, mutect2, varscan2
- ANKK1 | c.2145C>T p.G715= | Silent (SNP) | VAF 139/286 reads (49%) | catalogued as rs367992103; called by muse, mutect2, varscan2
- AR | c.132C>T p.A44= | Silent (SNP) | VAF 35/167 reads (21%) | called by muse, varscan2
- BHLHE22 | c.9C>T p.R3= | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- BMP2K | c.3219C>T p.P1073= | Silent (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- BTBD1 | c.30G>A p.G10= | Silent (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- CACNA1D | c.669C>T p.G223= | Silent (SNP) | VAF 139/139 reads (100%) | catalogued as rs756461282, COSV55442986; called by muse, mutect2, varscan2
- CACNA1S | c.477G>A p.L159= | Silent (SNP) | VAF 26/383 reads (7%) | catalogued as COSV100755433; called by muse, mutect2
- CASZ1 | c.1128C>T p.Y376= | Silent (SNP) | VAF 96/198 reads (48%) | catalogued as rs535551834, COSV100681306, COSV100682140; called by muse, mutect2, varscan2
- CDH5 | c.2253C>T p.S751= | Silent (SNP) | VAF 276/539 reads (51%) | catalogued as COSV58515638; called by muse, mutect2, varscan2
- CECR2 | c.3546C>A p.G1182= (on ENST00000342247 / NM_001290047.2; = p.G998= on NM_001290046.1) | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- COBL | c.3126C>T p.R1042= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs201043019; called by muse, varscan2
- COL27A1 | c.1077C>T p.I359= | Silent (SNP) | VAF 108/220 reads (49%) | catalogued as COSV61928911; called by muse, mutect2, varscan2
- DAB1 | c.999C>T p.Y333= (on ENST00000371231; = p.Y300= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs779410633, COSV64691287; called by muse, mutect2, varscan2
- EPHB4 | c.246C>T p.G82= | Silent (SNP) | VAF 47/516 reads (9%) | catalogued as rs373788065, COSV62268708; called by muse, mutect2
- ERICH2 | c.438C>T p.D146= | Silent (SNP) | VAF 92/222 reads (41%) | catalogued as rs935703660; called by muse, mutect2, varscan2
- FAM110B | c.522G>A p.P174= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as rs183366212, COSV64063953; called by muse, mutect2, varscan2
- GHRL | c.177G>A p.P59= | Silent (SNP) | VAF 21/228 reads (9%) | catalogued as rs113751742; called by muse, mutect2, varscan2
- HECW1 | c.1116G>A p.L372= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2
- INSYN1 | c.532C>A p.R178= | Silent (SNP) | VAF 67/118 reads (57%) | called by muse, mutect2, varscan2
- KIFC1 | c.870T>A p.L290= | Silent (SNP) | VAF 76/193 reads (39%) | called by muse, mutect2, varscan2
- LAIR1 | c.840G>A p.T280= | Silent (SNP) | VAF 78/145 reads (54%) | catalogued as rs746249343, COSV57306180; called by muse, mutect2, varscan2
- LAMA3 | c.8592C>T p.I2864= (on ENST00000313654 / NM_198129.4; = p.I1255= on NM_000227.6) | Silent (SNP) | VAF 205/423 reads (48%) | catalogued as rs779758375, COSV52535196; called by muse, mutect2, varscan2
- MCM9 | c.2961G>A p.Q987= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV60324826; called by muse, mutect2
- MRPL40 | c.621G>A p.*207= | Silent (SNP) | VAF 56/111 reads (50%) | called by muse, varscan2
- MUC16 | c.15840G>A p.S5280= | Silent (SNP) | VAF 76/173 reads (44%) | called by muse, mutect2, varscan2
- NPHS1 | c.3579C>T p.Y1193= | Silent (SNP) | VAF 202/410 reads (49%) | catalogued as rs747950877, COSV62286104; called by muse, mutect2, varscan2
- OBSCN | c.14295C>T p.D4765= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs751178093, COSV99470684; called by muse, mutect2
- OLIG2 | c.168C>T p.R56= | Silent (SNP) | VAF 23/337 reads (7%) | called by muse, mutect2
- PCDHA1 | c.201G>A p.A67= | Silent (SNP) | VAF 174/393 reads (44%) | catalogued as rs376604489; called by muse, mutect2, varscan2
- PDE1C | c.1737A>G p.T579= | Silent (SNP) | VAF 171/404 reads (42%) | catalogued as rs771548329; called by muse, mutect2, varscan2
- PPP1R3A | c.1395C>T p.N465= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- PTCHD3 | c.699C>T p.D233= | Silent (SNP) | VAF 128/269 reads (48%) | catalogued as rs1260956905, COSV71257235; called by muse, mutect2, varscan2
- RYR1 | c.4743C>T p.S1581= | Silent (SNP) | VAF 236/533 reads (44%) | catalogued as rs370041876; called by muse, mutect2, varscan2
- SLC35G4 | c.327G>T p.L109= | Silent (SNP) | VAF 189/430 reads (44%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.969C>T p.V323= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs866381547, COSV65805356; called by muse, mutect2, varscan2
- SOX17 | c.990C>T p.P330= | Silent (SNP) | VAF 224/496 reads (45%) | called by muse, mutect2, varscan2
- ST3GAL1 | c.669G>A p.T223= | Silent (SNP) | VAF 51/102 reads (50%) | catalogued as rs774739947; called by muse, mutect2, varscan2
- ST8SIA4 | c.102G>A p.T34= | Silent (SNP) | VAF 34/352 reads (10%) | catalogued as rs917045467, COSV51509639; called by muse, mutect2
- TNFAIP2 | c.1449C>T p.T483= | Silent (SNP) | VAF 279/580 reads (48%) | called by muse, mutect2, varscan2
- TSPEAR | c.1413C>T p.I471= | Silent (SNP) | VAF 47/458 reads (10%) | catalogued as rs369208247; called by muse, mutect2, varscan2
- UPP1 | c.798C>T p.A266= | Silent (SNP) | VAF 89/167 reads (53%) | catalogued as rs1044090475, COSV57977025; called by muse, mutect2, varscan2
- VCX3A | c.360G>A p.V120= | Silent (SNP) | VAF 227/712 reads (32%) | called by muse, varscan2
- ZFHX4 | c.7110G>A p.T2370= | Silent (SNP) | VAF 86/171 reads (50%) | catalogued as COSV50534522, COSV99254900; called by muse, mutect2, varscan2
- ZP4 | c.666G>A p.A222= | Silent (SNP) | VAF 23/217 reads (11%) | catalogued as rs536187390; called by muse, mutect2, varscan2
- ALG2 | c.*145A>G | 3'UTR (SNP) | VAF 136/289 reads (47%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505404 G>A | 5'Flank (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.244G>A | RNA (SNP) | VAF 215/495 reads (43%) | catalogued as rs770217898; called by muse, mutect2, varscan2
- CRYBB1 | c.432+41G>A | Intron (SNP) | VAF 13/261 reads (5%) | catalogued as rs954723276; called by muse, mutect2
- CSHL1 | c.191-54C>T | Intron (SNP) | VAF 195/555 reads (35%) | called by muse, mutect2, varscan2
- CTDP1 | c.*11C>T | 3'UTR (SNP) | VAF 152/327 reads (46%) | catalogued as rs376597291; called by muse, mutect2, varscan2
- DUSP22 | c.508+48C>T | Intron (SNP) | VAF 79/302 reads (26%) | catalogued as rs747000459; called by muse, mutect2, varscan2
- FCER2 | c.22+342T>C | Intron (SNP) | VAF 65/168 reads (39%) | called by muse, mutect2, varscan2
- FGD6 | c.3083-3221A>G | Intron (SNP) | VAF 37/171 reads (22%) | called by muse, mutect2, varscan2
- GUSBP3 | chr5:69635557 G>C | 3'Flank (SNP) | VAF 56/320 reads (18%) | catalogued as rs1275922109; called by mutect2, varscan2
- HAS1 | c.-33G>A | 5'UTR (SNP) | VAF 59/119 reads (50%) | called by muse, mutect2, varscan2
- IFT81 | c.1188+4840G>A | Intron (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- KLK1 | chr19:50818499 del C | 3'Flank (DEL) | VAF 53/129 reads (41%) | called by mutect2, pindel, varscan2
- LFNG | chr7:2528892 G>A | 3'Flank (SNP) | VAF 12/30 reads (40%) | catalogued as rs562235848, COSV56069254; called by muse, mutect2, varscan2
- LINC01169 | n.194T>A | RNA (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- MYO1F | c.-134G>A | 5'UTR (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- NAPEPLD | chr7:103149483 G>A | 5'Flank (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- OR5AK4P | n.438_441del | RNA (DEL) | VAF 60/172 reads (35%) | catalogued as rs1195015727; called by pindel, varscan2
- PACRG | c.614-67727C>A | Intron (SNP) | VAF 30/82 reads (37%) | catalogued as COSV61303693; called by muse, mutect2, varscan2
- PARGP1 | n.1023G>A | RNA (SNP) | VAF 155/487 reads (32%) | catalogued as rs1333800495; called by muse, mutect2, varscan2
- SHOX2 | c.346+566G>A | Intron (SNP) | VAF 128/310 reads (41%) | catalogued as rs770972796; called by muse, mutect2, varscan2
- TRIP4 | chr15:64387449 C>A | 5'Flank (SNP) | VAF 40/103 reads (39%) | called by muse, mutect2, varscan2
- TRPM3 | c.184-256801C>T | Intron (SNP) | VAF 88/178 reads (49%) | called by muse, mutect2, varscan2
